Somatic mutation profile of tumor specimen 0DWD44 from CCDI case PBCNPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.2 years (817 days).
Specimen 0DWD44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e99a697-a975-457a-ad74-2652f77fd4af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWD1M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e08ef34-8f55-48fd-9e18-d3da80ac55e6

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Intron 8, Nonsense Mutation 4, 3'UTR 2, Splice Site 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASIC1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 193/551 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1219107361; called by muse, mutect2, varscan2
- C12orf56 | c.968+1G>T p.X323_splice | Splice Site (SNP) | VAF 183/475 reads (39%) | catalogued as rs1318229290; called by muse, varscan2
- CIB3 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99521799; called by muse, mutect2
- CTLA4 | c.89T>G p.F30C | Missense Mutation (SNP) | VAF 121/1221 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV55592845; called by muse, mutect2, varscan2
- KIRREL1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs1412363703, COSV63289190; called by muse, varscan2
- LNPEP | c.2909C>A p.S970* | Nonsense Mutation (SNP) | VAF 93/923 reads (10%) | catalogued as COSV51478273; called by muse, mutect2, varscan2
- NUTM1 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 43/219 reads (20%) | catalogued as COSV100149195; called by muse, mutect2, varscan2
- PHF6 | c.872G>C p.G291A | Missense Mutation (SNP) | VAF 459/532 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99045875; called by muse, mutect2, varscan2
- PRELP | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 82/512 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV58117115; called by muse, mutect2, varscan2
- RPS6KA2 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1267156660; called by muse, mutect2
- SGO1 | c.1349A>G p.Y450C (on ENST00000263753 / NM_001012410.5; = p.Y181C on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/964 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55423152; called by muse, mutect2
- TAP2 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 131/698 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1421619062; called by muse, mutect2, varscan2
- TIAF1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 104/1254 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV62865202; called by muse, mutect2
- UPK1A | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs777131853; called by muse, mutect2, varscan2
- VAV3 | c.2180T>G p.F727C | Missense Mutation (SNP) | VAF 109/906 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100579441; called by muse, varscan2
- ASB2 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 12/438 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- B4GALNT4 | c.2014_2027del p.L672* | Frame Shift Del (DEL) | VAF 26/179 reads (15%) | called by mutect2, pindel
- CARF | c.617G>T p.W206L | Missense Mutation (SNP) | VAF 96/850 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC2 | c.743G>T p.R248I | Missense Mutation (SNP) | VAF 34/708 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- DENND4C | c.4978A>G p.R1660G (on ENST00000434457 / NM_001330640.2; = p.R1611G on NM_017925.7) | Missense Mutation (SNP) | VAF 93/597 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FNDC1 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 52/672 reads (8%) | called by muse, mutect2
- HCN2 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); called by mutect2, varscan2
- HERC2 | c.9719G>T p.G3240V | Missense Mutation (SNP) | VAF 101/582 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- HTR4 | c.959G>T p.R320I | Missense Mutation (SNP) | VAF 124/740 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- KPNA5 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 23/957 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- LGI2 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 27/522 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.074); called by muse, mutect2
- POLDIP2 | c.309T>A p.Y103* | Nonsense Mutation (SNP) | VAF 100/843 reads (12%) | called by muse, mutect2, varscan2
- SH3GL3 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 79/581 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC4A1 | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 30/698 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.158); called by muse, mutect2
- SLC5A7 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 41/1022 reads (4%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.034); called by muse, mutect2
- STIM1 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 122/789 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- STMP1 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 108/935 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SYNGR4 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TBC1D32 | c.936-1G>A p.X312_splice | Splice Site (SNP) | VAF 106/876 reads (12%) | called by muse, varscan2
- TESPA1 | c.819G>T p.E273D (on ENST00000316577 / NM_001098815.3; = p.E135D on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/985 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); called by muse, mutect2
- TUT7 | c.3373A>G p.T1125A | Missense Mutation (SNP) | VAF 44/896 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- ZNF628 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2
- AL592490.1 | c.1632C>T p.I544= | Silent (SNP) | VAF 216/1120 reads (19%) | catalogued as rs561712771, COSV69426684; called by muse, mutect2, varscan2
- BCL11B | c.2328C>T p.T776= (on ENST00000357195 / NM_001282237.2; = p.T705= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 114/291 reads (39%) | catalogued as rs769515267; called by muse, mutect2, varscan2
- ERC1 | c.2511C>T p.D837= (on ENST00000360905 / NM_178040.4; = p.D809= on NM_178039.4) | Silent (SNP) | VAF 28/1048 reads (3%) | called by muse, mutect2
- MUC22 | c.3204T>C p.S1068= | Silent (SNP) | VAF 104/650 reads (16%) | called by muse, mutect2
- PKP4 | c.75C>T p.G25= | Silent (SNP) | VAF 233/797 reads (29%) | called by muse, mutect2, varscan2
- RBM25 | c.999T>C p.R333= | Silent (SNP) | VAF 302/745 reads (41%) | called by muse, varscan2
- RNASE3 | c.6T>C p.V2= | Silent (SNP) | VAF 42/370 reads (11%) | called by muse, mutect2, varscan2
- SLC26A4 | c.432G>C p.V144= | Silent (SNP) | VAF 212/959 reads (22%) | catalogued as COSV55915603; called by muse, mutect2, varscan2
- VAMP8 | c.109C>A p.R37= | Silent (SNP) | VAF 43/568 reads (8%) | called by muse, mutect2
- ACP5 | c.390-21C>T | Intron (SNP) | VAF 58/285 reads (20%) | catalogued as rs761983850; called by muse, mutect2, varscan2
- APH1B | c.356-29G>T | Intron (SNP) | VAF 143/633 reads (23%) | called by muse, varscan2
- CCDC88B | c.2958+60C>T | Intron (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- CLDN8 | c.-23G>A | 5'UTR (SNP) | VAF 48/308 reads (16%) | called by muse, mutect2, varscan2
- GH2 | c.456+58G>A | Intron (SNP) | VAF 25/750 reads (3%) | catalogued as rs1192602569; called by muse, mutect2
- GSG1 | c.49-4872C>A | Intron (SNP) | VAF 32/183 reads (17%) | called by muse, mutect2, varscan2
- IKBKB | c.1688+32C>A | Intron (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- LST1 | c.*44C>T | 3'UTR (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- PLCZ1 | c.135+23C>T | Intron (SNP) | VAF 89/657 reads (14%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.*85C>T | 3'UTR (SNP) | VAF 21/194 reads (11%) | catalogued as rs555827884; called by muse, mutect2, varscan2
- SH3BP5L | c.375+57C>A | Intron (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
